Surgical pathology report (de-identified scan), TCGA case TCGA-HC-8266, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-8266-01A (Primary Tumor).

[page 1 of 3]
Patient Results

Path Report

Final

SURGICAL PATHOLOGY REPORT

ACCESSION NO. : [REDACTED]

Final Diagnosis(es):

(A) Prostate and seminal vesicles, total prostatectomy:

1) Bilateral prostate adenocarcinoma, Gleason sub score
4+4 = 8/10.

2) Largest tumor posterior central.

3) Estimated volume: 5.0 x 2.0 x 1.5 cm - 15 cc.

4) Bilateral capsular penetration (slides A 32, A33, A39).

5) Bilateral extension into seminal vesicle with positive
surgical margin.

6) Pathologic stage: pT3bN0MX (see Synoptic report, below).

(B) Pelvic lymph nodes, bilateral, excision: 5 lymph nodes,
negative for neoplasia (0/5).

Synoptic Report:

Diagnosis: Prostate adenocarcinoma.

Procedure: Radical prostatectomy.

Specimen Size: 4.5 x 4.0 x 4.0 cm.

Specimen Weight: 50 gm.

Lymph Node Sampling: Pelvic lymph node dissection.

Histologic Type: Adenocarcinoma, acinar type.

Histologic Grade (Gleason pattern)

Primary Pattern: Grade 4

Secondary Pattern: Grade 4

Total Gleason Score: 8/10

Percent of Prostate Involved: 30%

Size of Dominant Nodule

Greatest dimension: 5.0 cm.

Additional dimensions: 2.0 x 1.5 cm.

Extraprostatic Extension: Nonfocal.

Seminal Vesicle Invasion:

Left: Positive

Right: Positive

Lymphovascular Invasion: Positive

Margins:

Apical: Negative.

Bladder neck: Negative.

Anterior: Negative.

Lateral: Negative.

Posterolateral: Negative.

Posterior: Positive.

Nodes: Node Group: Bilateral pelvic lymph nodes

Total: 5

Positive: 0

Pathologic Stage: pT3bN0pMX

[page 2 of 3]
Patient Results

Electronically Signed [REDACTED]

Specimen(s) Received:

A: prostate w/ seminal vesicles

B: bil pelvic LN

Clinical History:

Prostate CA. [REDACTED]

Gross Description:

(A) (prostate and seminal vesicles) Received fresh is a prostate and attached seminal vesicles. The prostate weighs 50 gm and measures 4.5 x 4.0 x 4.0 cm. The entire external surface is inked as follows: Right red, left green and posterior black stripe. The prostate is totally embedded as follows:

A1-A9 - apex, submitted from right to left

A10-A13 - level 1

A14-A17 - level 2

A18-A21 - level 3

A22-A25 - level 4

A26-A29 - level 5

A30-A35 - level 6

A36-A39 - level 7

A40-A43 - level 8

A44-A45 - level 9

A56-A51 - right seminal vesicle submitted proximally to distally

A52-A58 - left seminal vesicle submitted proximally to distally

(B) (bilateral pelvic lymph nodes) Received in formalin are numerous fragments of soft tan-yellow fibroadipose tissue measuring 5.0 x 4.5 x 2.5 cm in aggregate with the largest fragment having a largest dimension of 3.0 cm. dissection of the specimen reveals five possible lymph nodes ranging in size from 3.0 cm to 0.5 cm in greatest dimension. The specimen is submitted as follows:

B1-B2 - one lymph node bisected submitted entirely

B3-B5 - one lymph node serially sectioned submitted entirely

B6-B7 - one lymph node bisected submitted entirely

B8 - two lymph nodes submitted entirely

Microscopic Description:

Complete microscopic evaluation has been performed. [REDACTED]

Appropriately reacting controls have been performed and evaluated for all stains on this case as required.

Histopathology has a list of IH antibodies that are regulated as analyte specific reagents (ASR's). These assays were developed and their performance characteristics determined by the Histopathology Laboratory in the Department of Pathology at The [REDACTED]

[REDACTED] - [REDACTED] They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary for the ASR's. These tests are not investigational

[page 3 of 3]
Patient Results

and are used in standard clinical care. In cases where Immunohistochemistry testing is performed, the following antibodies and their respective clones may be used to determine therapy for the patient: EGFR(31G7), ER(SP1), PR(1E2), Her2neu(4B5), CD117(Poly), CD20(L26).

Unless otherwise stated in the report, all tissue tested for ERPR by IHC, Her2 by IHC and/or HER2 by FISH have been fixed as per ANP.22998 for a minimum of 6 hours and a maximum of 48 hours.

ER, PR, Ki-67, p53 are reported as a semi-quantitative percentage of positively stained nuclei. Her-2/neu and EGFR are scored as follows: No staining at all is scored as (0), weak, incomplete membrane staining in any proportion of cells is scored as (1+), less than strong but complete staining in any proportion of cells or complete strong staining in less than 30% of cells is scored as (2+), and strong complete staining in more than 30% of cells is scored as (3+). All studies are performed on tissue fixed in 10% neutral buffered formalin and embedded in paraffin unless otherwise stated in the report.

Source: NCI Genomic Data Commons file 1cc2e2b0-88c8-4a60-990c-f83d2a775c65 (TCGA-HC-8266.CB8ABDBD-C61D-4AD4-BD8B-A7E9DBC20D2D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).